Somatic mutation profile of tumor specimen C3N-03092-01 (aliquot CPT0197480006) from CPTAC case C3N-03092, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-03092-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10ee2612-6342-494c-b17d-403fedfb6797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03092-71 (Blood Derived Normal), aliquot CPT0197660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99ba8b7e-cdf7-4ec0-b74d-76e529319fed

The open-access MAF lists 174 somatic variants for this specimen: 116 protein-altering or splice-affecting, 42 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 42, Nonsense Mutation 12, Intron 7, Frame Shift Del 4, RNA 3, 3'Flank 3, Splice Site 2, 5'Flank 2, Nonstop Mutation 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 197/670 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1A | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52926311; called by muse, mutect2, varscan2
- ARMC6 | c.608G>A p.R203H (on ENST00000392336; = p.R178H on NM_033415.4) | Missense Mutation (SNP) | VAF 27/447 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs373198003; called by muse, mutect2
- CAPN15 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 30/541 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1472167786; called by muse, mutect2
- CASR | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV56133872; called by muse, mutect2
- CCDC39 | c.2296C>T p.H766Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs546887443, COSV56479766; called by muse, varscan2
- CDH18 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1287507809, COSV56935740; called by muse, mutect2
- CEP170B | c.3146G>A p.R1049H (on ENST00000453495; = p.R978H on NM_015005.3) | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs540741393; called by muse, mutect2
- CFLAR | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 65/370 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs1260523971; called by muse, mutect2, varscan2
- CHDH | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 28/372 reads (8%) | catalogued as rs1182280377; called by muse, mutect2
- CNTNAP2 | c.1853G>A p.G618D | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62194222; called by muse, mutect2, varscan2
- DAPP1 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 16/262 reads (6%) | catalogued as COSV56449595; called by muse, mutect2
- DDX53 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1294969247; called by muse, mutect2, varscan2
- FLG2 | c.1765C>A p.Q589K | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV66174452; called by muse, mutect2
- GOLPH3L | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as rs1337706573; called by muse, mutect2
- GRM4 | c.2372T>A p.M791K | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100945695; called by muse, mutect2
- IMPACT | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52422959; called by muse, mutect2
- IRAG1 | c.1733C>G p.A578G | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV101351063; called by muse, mutect2
- ITGA7 | c.3128G>C p.R1043P (on ENST00000555728; = p.R999P on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/511 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99149897; called by muse, mutect2
- MCM6 | c.1473T>A p.A491= | Splice Region (SNP) | VAF 8/82 reads (10%) | catalogued as COSV51468994; called by muse, mutect2
- MRPL49 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as rs368573831; called by muse, mutect2, varscan2
- NOL6 | c.2527G>A p.G843R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485256346, COSV53040919; called by muse, mutect2
- OR10Z1 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747788570; called by muse, mutect2, varscan2
- OR14I1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs767063023, COSV61199263, COSV61199290; called by muse, mutect2
- PAPPA2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62783918; called by muse, mutect2
- PCLO | c.5876C>G p.S1959C | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100434467; called by muse, mutect2
- PPP4R3B | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs576584835, COSV55401749; called by muse, mutect2
- PRR27 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1253758134, COSV60641714; called by muse, mutect2
- PSG2 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.17); catalogued as rs1190445513; called by muse, mutect2, varscan2
- RETREG3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs141316520; called by muse, mutect2
- SETBP1 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56339799; called by muse, mutect2
- SLC25A12 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 75/305 reads (25%) | catalogued as COSV55532159; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.917G>T p.*306Lext*1 | Nonstop Mutation (SNP) | VAF 14/156 reads (9%) | catalogued as COSV60322588; called by muse, mutect2
- TENM3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as rs751022917; called by muse, mutect2
- TET1 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV65384379; called by muse, mutect2
- THBD | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1180969420; called by muse, mutect2
- TIGD3 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs769191642; called by muse, mutect2
- UGGT2 | c.2101G>T p.V701L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs1310074521; called by muse, mutect2
- VPS13D | c.11281G>A p.E3761K | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV50636618; called by muse, mutect2
- XIRP2 | c.9828C>A p.F3276L (on ENST00000628543; = p.F3451L on NM_152381.6) | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54714367; called by muse, mutect2
- ZNF251 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99478926; called by muse, mutect2
- AASS | c.2514G>A p.M838I | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ADCY2 | c.992G>A p.C331Y | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGXT2 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 198/711 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP7 | c.1014G>C p.Q338H (on ENST00000431975 / NM_016377.4; = p.Q71H on NM_004842.4) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2
- ARHGEF26 | c.1871C>A p.A624D | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID1A | c.323del p.G108Afs*6 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- BEND7 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- C6 | c.2353A>G p.I785V | Missense Mutation (SNP) | VAF 23/466 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CDH19 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.202); called by muse, mutect2
- CFHR4 | c.550G>T p.G184* (on ENST00000367416 / NM_001201551.2; = p.G185* on NM_001201550.3) | Nonsense Mutation (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- CHI3L2 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.042); called by muse, mutect2
- CIITA | c.1912A>C p.T638P | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP2 | c.3358C>A p.H1120N | Missense Mutation (SNP) | VAF 76/417 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL23A1 | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPSF4 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 27/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.5075T>C p.L1692P (on ENST00000520002; = p.L1691P on NM_033225.6) | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); called by mutect2, varscan2
- DNAJA3 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- DNAJC27 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- DPP10 | c.1871T>A p.V624E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, varscan2
- DSTYK | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- EP300 | c.1613A>C p.N538T | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2
- FGD2 | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- GPRIN1 | c.3022G>T p.E1008* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- GRIN3A | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.085); called by muse, mutect2
- H2AC11 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 22/444 reads (5%) | called by muse, mutect2
- INPP4A | c.1852C>G p.P618A (on ENST00000074304 / NM_001134224.1; = p.P579A on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IQUB | c.726G>C p.E242D | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2
- ITPKB | c.2407A>T p.I803F | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- LIN37 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- LRCH1 | c.661A>C p.N221H | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAM2 | c.6137C>T p.P2046L | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- MICALL1 | c.2443del p.M815Cfs*5 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- MYLK4 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NATD1 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- NECTIN4 | c.1309-1G>T p.X437_splice | Splice Site (SNP) | VAF 31/532 reads (6%) | called by muse, mutect2
- NOA1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 32/409 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.143); called by muse, mutect2
- NRXN3 | c.738C>A p.N246K (on ENST00000557594 / NM_001272020.2; = p.N878K on NM_004796.6) | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2
- NT5C1B | c.1586G>T p.C529F (on ENST00000359846 / NM_001199086.2; = p.C469F on NM_033253.4) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR10Z1 | c.319T>A p.W107R | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- OR6V1 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 13/385 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2
- PPP2CA | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- PRMT6 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2
- PRR36 | c.1441del p.L481Wfs*12 | Frame Shift Del (DEL) | VAF 24/190 reads (13%) | called by pindel, varscan2
- PRR36 | c.1433C>A p.A478D | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.03); called by muse, varscan2
- PSKH2 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- PURG | c.1004del p.G335Afs*30 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- RBM45 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RHOBTB3 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- RNF214 | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, mutect2
- RO60 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); called by muse, mutect2
- RYR2 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- SCLY | c.985G>T p.A329S (on ENST00000651534; = p.A321S on NM_016510.7) | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); called by muse, mutect2
- SDK2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2
- SEMA5A | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- SH2D3C | c.1163A>T p.D388V (on ENST00000314830 / NM_170600.3; = p.D231V on NM_005489.4) | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SHANK1 | c.2042C>G p.A681G | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SHQ1 | c.1021A>C p.M341L | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA31E1 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.271); called by muse, mutect2
- SSX2IP | c.1748G>T p.W583L | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- STPG2 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STPG3 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- TAOK3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TNS3 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- TRIM37 | c.1167C>G p.Y389* | Nonsense Mutation (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- TRIM46 | c.372A>T p.Q124H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TRIO | c.6658-2A>T p.X2220_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- TTC9 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.487); called by muse, mutect2
- UBXN7 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VWA5B1 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ZBTB11 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZHX2 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- ZNF131 | c.965G>C p.R322T (on ENST00000509156 / NM_001330707.2; = p.R288T on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF862 | c.2908C>T p.L970F | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZSCAN20 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2
- ACACA | c.2922C>T p.P974= | Silent (SNP) | VAF 29/227 reads (13%) | catalogued as rs1471446489; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2370C>T p.S790= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs765796730; called by muse, mutect2, varscan2
- ADRA1B | c.168C>T p.I56= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- AHNAK2 | c.3051C>T p.I1017= | Silent (SNP) | VAF 131/587 reads (22%) | catalogued as COSV60929771; called by muse, mutect2, varscan2
- ASXL3 | c.1005G>T p.R335= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- BMT2 | c.798G>T p.L266= | Silent (SNP) | VAF 54/234 reads (23%) | called by muse, mutect2, varscan2
- CAPN5 | c.2031C>T p.L677= (on ENST00000456580; = p.L637= on NM_004055.5) | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CDCA5 | c.537A>G p.G179= | Silent (SNP) | VAF 41/392 reads (10%) | called by muse, mutect2, varscan2
- CLRN2 | c.453C>G p.A151= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, varscan2
- COL4A5 | c.342G>T p.G114= | Silent (SNP) | VAF 76/207 reads (37%) | called by muse, mutect2, varscan2
- COL5A1 | c.1044G>A p.T348= | Silent (SNP) | VAF 40/669 reads (6%) | catalogued as rs1246095864, COSV65666267; ClinVar: likely benign; called by muse, mutect2
- ECI1 | c.579G>A p.L193= | Silent (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- ESRRG | c.912T>G p.A304= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as COSV63148189; called by muse, mutect2
- FBLN7 | c.579G>C p.A193= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as rs1197516958, COSV55615782; called by muse, mutect2, varscan2
- FIGN | c.195C>A p.S65= | Silent (SNP) | VAF 15/191 reads (8%) | called by muse, mutect2
- GLI1 | c.1764G>T p.L588= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- GSTP1 | c.606C>T p.L202= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2
- HOXD12 | c.114G>T p.A38= | Silent (SNP) | VAF 11/159 reads (7%) | catalogued as COSV66832386, COSV66832421; called by muse, mutect2
- HSPG2 | c.12117G>A p.S4039= | Silent (SNP) | VAF 28/470 reads (6%) | catalogued as rs772338296; called by muse, mutect2
- KDM5A | c.3313C>T p.L1105= | Silent (SNP) | VAF 40/361 reads (11%) | called by muse, mutect2, varscan2
- LRP5 | c.4179C>T p.I1393= | Silent (SNP) | VAF 32/696 reads (5%) | called by muse, mutect2
- MAP3K13 | c.2256G>C p.G752= | Silent (SNP) | VAF 9/247 reads (4%) | catalogued as COSV53993248; called by muse, mutect2
- NTPCR | c.532C>T p.L178= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- OR13A1 | c.9G>T p.L3= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV65572193; called by muse, mutect2
- OR51S1 | c.678C>A p.G226= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs533188649; called by muse, mutect2, varscan2
- PITPNB | c.576C>G p.A192= | Silent (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- PLCH2 | c.57G>A p.L19= | Silent (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- PLVAP | c.1095G>T p.L365= | Silent (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2445G>A p.L815= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- PTPRF | c.2148G>A p.E716= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- RDH5 | c.822T>G p.A274= | Silent (SNP) | VAF 50/592 reads (8%) | called by muse, mutect2
- RIMS2 | c.4737A>G p.S1579= (on ENST00000666250 / NM_001348490.2; = p.S1150= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 96/271 reads (35%) | called by muse, mutect2, varscan2
- RNF224 | c.333C>G p.L111= | Silent (SNP) | VAF 35/536 reads (7%) | called by muse, mutect2
- RRP1 | c.696C>G p.L232= | Silent (SNP) | VAF 9/183 reads (5%) | catalogued as COSV101513891; called by muse, mutect2
- SH3BP2 | c.972C>T p.A324= | Silent (SNP) | VAF 43/409 reads (11%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.126G>A p.Q42= | Silent (SNP) | VAF 18/347 reads (5%) | called by muse, mutect2
- TACC2 | c.3183A>C p.P1061= | Silent (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
- TET1 | c.825A>C p.S275= | Silent (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2
- TEX52 | c.759G>A p.K253= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- TNFSF13B | c.768A>G p.G256= | Silent (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- WDR89 | c.843A>G p.L281= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs755486051; called by muse, mutect2, varscan2
- ZFHX3 | c.9873G>C p.L3291= | Silent (SNP) | VAF 23/414 reads (6%) | called by muse, mutect2
- ACTG1 | chr17:81512806 C>T | 5'Flank (SNP) | VAF 10/250 reads (4%) | catalogued as rs782002233; called by muse, mutect2
- ANKRD42 | chr11:83193772 del T | 5'Flank (DEL) | VAF 11/94 reads (12%) | called by mutect2, pindel
- C5orf60 | n.1771C>A | RNA (SNP) | VAF 48/728 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*3225G>A | 3'UTR (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- DBT | c.1017+42G>C | Intron (SNP) | VAF 10/120 reads (8%) | catalogued as rs952837420; called by muse, mutect2
- DIO3OS | chr14:101552557 C>A | 3'Flank (SNP) | VAF 50/248 reads (20%) | called by muse, mutect2, varscan2
- EMC3 | c.156-4290C>G | Intron (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- GPS1 | c.33+316del | Intron (DEL) | VAF 34/292 reads (12%) | called by mutect2, pindel, varscan2
- MORF4 | n.749del | RNA (DEL) | VAF 17/162 reads (10%) | called by mutect2, varscan2
- POM121 | chr7:72950027 C>T | 3'Flank (SNP) | VAF 25/578 reads (4%) | catalogued as COSV99988062; called by muse, mutect2
- PRSS12 | c.1489+22C>T | Intron (SNP) | VAF 20/303 reads (7%) | called by muse, mutect2
- RFPL4AL1 | chr19:55777694 G>A | 3'Flank (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-51545G>C | Intron (SNP) | VAF 6/119 reads (5%) | catalogued as COSV67440801; called by muse, mutect2
- SNORD116-5 | n.3A>T | RNA (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- TM7SF3 | c.91+1318C>T | Intron (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- VGLL3 | c.937+5599A>T | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
